Surgical pathology report (de-identified scan), TCGA case TCGA-B9-4113, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-4113-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Diagnosis:

A: Kidney, left, laparoscopic nephrectomy.

- Renal cell carcinoma, papillary type, grade 2 (of 4, Furhman classification), 5.8 cm diameter, extending into but not through capsule, without angiolymphatic invasion, surgical margins not involved.
- Medullary fibromata, multiple.

B: Testicle, right, orchiectomy.

- Benign testicular parenchyma, mild decreased spermatogenesis, no neoplasm identified.

C: Testicle, left, orchiectomy.

- Benign testicular parenchyma, mild decreased spermatogenesis, no neoplasm identified.

Comment:

None.

Clinical History:

Patient is with a clinical diagnosis of prostate carcinoma and a renal mass, in for left laparoscopic nephrectomy and bilateral orchiectomy.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "left kidney."

Specimen fixation: formalin

Type of specimen: laparoscopic nephrectomy

Size and weight of specimen: 650 grams, approximately 19 x 11 x 5.2 cm nephrectomy specimen

Presence/absence of adrenal gland: absent

Tumor description: there is a well circumscribed soft yellow lower pole mass; the majority of the inner portion

[page 2 of 4]
of the mass is markedly hemorrhagic; there are no cysts or areas of calcification noted; the mass is in the medulla but is compressing the pelvis

Tumor size: approximately 5.8 x 4.0 x 2.9 cm

Presence/absence of multicentricity: absent

Confinement/Non-confinement to kidney: confined

Extent of invasion:

Perirenal adipose tissue: tumor does not grossly involve

Renal vein: tumor does not grossly involve

Ureter: tumor does not grossly involve

Other organs: n/a

Surgical margins:

Perirenal adipose tissue: grossly negative

Renal vein: grossly negative

Renal artery: grossly negative

Ureter: grossly negative

Description of kidney away from tumor: The remainder of the kidney is pink/tan with a relatively distinct corticomedullary junction with a cortex measuring approximately 0.6 cm, the medulla measuring approximately 1.3 cm; additionally, there are three firm, white nodules noted in the cortex up to 0.5 x 0.3 x 0.3 cm; these nodules do not grossly resemble the main tumor mass.

Lymph nodes (hilar): No hilar lymph node candidates are palpated.

Tissue submitted for special investigations: A small section of tumor and normal tissue were given to Tissue Procurement.

Block Summary:

- A1 - ureter and hilar vascular margins
- A2 - tumor and adjacent kidney
- A3 - tumor and capsule, tumor and adjacent kidney
- A4, A5 - additional tumor
- A6 - representative from three firm white cortical nodules
- A7, A8 - representative normal kidney
- A9 - representative hilar fat
- A10 - additional possible ureter margin

[page 3 of 4]
All - lymph node candidates

Container B is additionally labeled "right testicle." It holds a 37.1 gram, 5.5 x 3.0 x 2.5 cm testicle with approximately 3.5 x 1.2 x 1.0 cm attached epididymis. The external surface of the testicle and the epididymis is tan, smooth and glistening. The external surface is inked blue to exhibit grossly unremarkable orange/pink, soft testicular parenchyma. The tunica vaginalis is approximately 0.1 cm thick, intact and grossly unremarkable. The testicular parenchyma is grossly unremarkable. No masses or lesions are identified in either testicular or epididymal cut surfaces. Representative sections are submitted per block summary.

B1 - spermatic cord margin

B2 - testicle

B3 - testicle and epididymis

Container C is additionally labeled "left testicle." It holds a 40.3 gram, 5 x 3.3 x 3.0 cm testicle with attached approximately 5.5 x 2.0 cm epididymis. The external surface of both the testicle and epididymis is tan, smooth and glistening. The external surface is inked blue and the testicle is bivalved to exhibit orange/brown soft testicular parenchyma with no gross lesions or masses identified. The tunica vaginalis is intact and on average 0.1 cm thick. Sections are submitted as per block summary.

C1 - spermatic cord margin

C2 - testicle

C3 - testicle and epididymis

Light Microscopy:

Light microscopic examination is performed

Histologic tumor type/subtype: renal cell carcinoma/papillary subtype

Histologic grade (if applicable): grade 2 (of 4, Furhman classification)

Tumor size (greatest dimension): grossly 5.8 cm diameter

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: extension into

[page 4 of 4]
but not through capsule in block A3
Renal vein: not involved
Ureter: not involved
Blood vascular: not identified
Lymphovascular: not identified
Depth of invasion:
Adjacent organs: no adrenal received

Histologic assessment of surgical margins: negative

Adrenal gland: not included

Lymph nodes: none sampled

Other significant findings: non-neoplastic kidney shows
scattered medullary fibromata

Source: NCI Genomic Data Commons file 73e71ebf-3050-4209-9503-bd269caaed84 (TCGA-B9-4113.65422F07-C2B3-4387-8D09-702E27FD35E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).